Somatic mutation profile of tumor specimen MP2PRT-PANZBY-TBP1-A (aliquot MP2PRT-PANZBY-TBP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PANZBY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,044 days).
Specimen MP2PRT-PANZBY-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0037ff1b-029f-47e0-95a7-292e4d19118d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANZBY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANZBY-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3471dbce-e174-440f-a875-3e3e791d180f

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 137/432 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CREB5 | c.188C>T p.T63M (on ENST00000357727 / NM_182898.4; = p.T56M on NM_004904.3) | Missense Mutation (SNP) | VAF 122/351 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs762102181, COSV63220795; called by muse, mutect2, varscan2
- SPEM3 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 157/539 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs142001182; called by muse, mutect2, varscan2
- TFAP4 | c.12C>A p.F4L | Missense Mutation (SNP) | VAF 130/352 reads (37%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.827); catalogued as COSV99200048; called by muse, mutect2, varscan2
- TICRR | c.5116G>A p.G1706S | Missense Mutation (SNP) | VAF 219/585 reads (37%) | SIFT tolerated (0.85); PolyPhen benign (0.011); catalogued as rs561088196; called by muse, mutect2, varscan2
- ENTPD8 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 60/427 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- EPPK1 | c.4131G>A p.A1377= | Silent (SNP) | VAF 274/713 reads (38%) | catalogued as rs370174488; called by muse, mutect2, varscan2
- FAM53A | c.417C>T p.P139= | Silent (SNP) | VAF 255/991 reads (26%) | catalogued as rs535498522; called by muse, mutect2, varscan2
- PCDHA9 | c.1722C>T p.D574= | Silent (SNP) | VAF 341/894 reads (38%) | catalogued as rs781838621, COSV65327786; called by muse, mutect2, varscan2
